Somatic mutation profile of tumor specimen TARGET-20-PANAEV-09A (aliquot TARGET-20-PANAEV-09A-03D) from TARGET case TARGET-20-PANAEV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.7 years (3,539 days).
Specimen TARGET-20-PANAEV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7867562-b0e8-43f6-b549-3a7c5ce4ab6c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANAEV-14A (Bone Marrow Normal), aliquot TARGET-20-PANAEV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cc36c9f-7e69-4340-b0ba-b28540a576ad

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 14/205 reads (7%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PTPN11 | c.1504T>G p.S502A | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs121918458, CM022450, CM055504, COSV61005465, COSV61007751, COSV61015981; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.863_864insCATG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 20/67 reads (30%) | catalogued as rs1554138188, COSV51544217, COSV51551832, COSV51558469, COSV51558827, COSV51561854; called by mutect2, pindel, varscan2
- LILRB3 | c.-52G>A | 5'UTR (SNP) | VAF 31/95 reads (33%) | called by muse, mutect2
